TCGA case TCGA-3U-A98H — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: University of Chicago. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3d8b4046-822a-4a00-b79e-393bd3f5f5b5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 57 years; Vital status: Dead; Days to death: 1,156 days (3.2 years).

Diagnoses (7)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 57.6 years (21,034 days); Year of diagnosis: 2010; Method of diagnosis: Imaging; AJCC staging edition: 7th; AJCC pathologic T: T4; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,156 days (3.2 years).
   Pathology details: Consistent pathology review: No.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Tivantinib; Days to treatment start: 910 days (2.5 years); Days to treatment end: 1,022 days (2.8 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Recorded as not given: Pleurodesis, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Thorax, NOS. Age at diagnosis: 58.8 years (21,468 days); Days to diagnosis: 434 days (1.2 years); Prior treatment: Yes.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 59.8 years (21,832 days); Days to diagnosis: 798 days (2.2 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS.
4. Progression of diagnosis 1 (Epithelioid mesothelioma, malignant). Age at diagnosis: 59.8 years (21,832 days); Days to diagnosis: 798 days (2.2 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.
5. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 60.2 years (22,000 days); Days to diagnosis: 966 days (2.6 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS.
6. Progression of diagnosis 1 (Epithelioid mesothelioma, malignant). Age at diagnosis: 60.2 years (22,000 days); Days to diagnosis: 966 days (2.6 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.
7. Metastasis of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Lung, NOS. Age at diagnosis: 60.4 years (22,072 days); Days to diagnosis: 1,038 days (2.8 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (8 entries)
- Day 434 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thorax, NOS; Days to recurrence: 434 days (1.2 years).
- Day 798 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Days to progression: 798 days (2.2 years).
- Day 966 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Days to progression: 966 days (2.6 years).
- Day 1,038 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 1,038 days (2.8 years).
- Day 1,038 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Days to progression: 1,038 days (2.8 years).
- Days to follow up: 1,150 days (3.1 years); Disease response: With Tumor.
- Days to follow up: 1,156 days (3.2 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Post Adjuvant Therapy.

Molecular and laboratory tests
- Creatinine 0.9 mg/dL [Blood test normal range lower: 0.5; Blood test normal range upper: 1.4].

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3U-A98H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 110 mg.
  Slide TCGA-3U-A98H-01A-01-TS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 35; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
  Slide TCGA-3U-A98H-01A-02-TS2: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
- Sample TCGA-3U-A98H-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3U-A98H-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Biphasic mesothelioma; Mesothelioma detection method: Thorascopy.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment: Pharmaceutical therapy drug name: Tivantinib (ARQ-197); Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,156 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,156 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 798 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3U-A98H-01A-11D-A39Q-01): tumor purity 0.38, ploidy 2.03, whole-genome doublings 0.
